Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A1QS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A1QS-01A (Primary Tumor).

Cervical

Date of Procurement

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Report:

UTERUS TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 4 x 3 x 3 cm

Histologic type: Squamous cell carcinoma, large cell, non-keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Extent of myometrial invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Laterality:

NA

ICD-0-3

carcinoma, squamous cell, large cell,
nonkeratinizing 8072/3

Site: cervix, NOS C53.9 4/8/11 lw

Cash if (Specify)		

4/8/11

Source: NCI Genomic Data Commons file 1f5ffe74-ebc0-4a51-a301-23c444ccfc14 (TCGA-EA-A1QS.827FEDD4-5D89-4706-A81D-DAFA017EC7FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).